TCGA case TCGA-FA-A6HO — Lymphoid Neoplasm Diffuse Large B-cell Lymphoma (TCGA-DLBC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mature B-Cell Lymphomas; Primary site: Lymph nodes; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/69f23725-adca-48ac-9b33-80a7aae24cfe

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Vietnam; Age at index: 58 years; Vital status: Alive.

Diagnoses (2)
1. Diffuse large B-cell lymphoma, NOS (the primary disease): ICD-O-3 morphology code: 9680/3; ICD-10 code: C83.3; Tissue or organ of origin: Lymph nodes of head, face and neck; Site of resection or biopsy: Lymph nodes of head, face and neck; Classification of tumor: primary; Age at diagnosis: 58.4 years (21,330 days); Year of diagnosis: 2013; AJCC staging edition: 7th; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 749 days (2.1 years); Ann Arbor extranodal involvement: No; Max tumor bulk site: Cervical lymph nodes; Sites of involvement: Lymph Node, Cervical.
   Pathology details: Additional pathology findings: Percent follicular component <= 10%.
   Pathology details: Consistent pathology review: Yes; Greatest tumor dimension: 1.5 cm; Measurement unit: Centimeters.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CHOP-14; Days to treatment start: 10 days; Days to treatment end: 71 days; Number of cycles: 4.
   Recorded as not given: adjuvant Radiation Therapy, NOS; Stem Cell Transplantation, NOS.
2. Progression of diagnosis 1 (Diffuse large B-cell lymphoma, NOS), site: Intra-abdominal lymph nodes. Age at diagnosis: 60.4 years (22,069 days); Days to diagnosis: 739 days (2.0 years); Prior treatment: Yes.

Follow-up (5 entries)
- Days to follow up: 6 days; Disease response: Tumor Free.
- Days to follow up: 400 days (1.1 years); Disease response: Tumor Free.
- Day 739 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Intra-abdominal lymph nodes; Days to progression: 739 days (2.0 years).
- Days to follow up: 749 days (2.1 years); Disease response: With Tumor.
- Follow-up contact recording only the day: within 2 months after completion of first-course treatment.

Molecular and laboratory tests
- CD20 (IHC): Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 61 kg; Height: 158 cm; BMI: 24.4.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FA-A6HO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 140 mg.
  Slide TCGA-FA-A6HO-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 75; Percent monocyte infiltration: 15; Percent neutrophil infiltration: 5.
- Sample TCGA-FA-A6HO-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FA-A6HO-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free.
- Stage record, Ann arbor: B symptoms present indicator: No.
- History of disease: HIV status: Negative.
- Primary pathology: Follicular component percent: < or = 10%; Maximum tumor bulk anatomic site: Cervical; Bone marrow biopsy performed: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Tests performed, Genetic testing results, Genetic testing result: Immunopheotypic analysis tested: CD20; Immunophenotypic analysis method: Immunohistochemistry.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.
- Drug treatment 1: Stem cell transplantation: No.
- Drug treatment 2: Pharmaceutical therapy drug name: Adriamycin; Stem cell transplantation: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 749 days; disease-specific survival: no event (censored), 749 days; disease-free interval: event (new tumor event after initially disease-free), 739 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 739 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FA-A6HO-01A-11D-A31W-01): tumor purity 0.3, ploidy 5.23, whole-genome doublings 2.
